Somatic mutation profile of tumor specimen TCGA-06-0195-01B (aliquot TCGA-06-0195-01B-01D-1491-08) from TCGA case TCGA-06-0195, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,132 days).
Specimen TCGA-06-0195-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c50d4d2e-d3a5-47bd-a3a6-0bc014eeb588.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0195-10A (Blood Derived Normal), aliquot TCGA-06-0195-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1791fc4-2217-4b61-b9db-9a5881646512

The open-access MAF lists 72 somatic variants for this specimen: 58 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 12, Nonsense Mutation 3, RNA 2, In Frame Ins 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 73/114 reads (64%) | catalogued as rs1566196458, CM144780, COSV57295836, COSV99927764; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.842A>C p.D281A | Missense Mutation (SNP) | VAF 32/98 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, varscan2
- AADAC | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 81/152 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs530863195, COSV51759204; called by muse, mutect2, varscan2
- ABCB4 | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs886044649, COSV55935071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.1849A>G p.K617E | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs762710163, COSV56988669; called by muse, mutect2, varscan2
- BCL9L | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs774747102, COSV58311198; called by muse, varscan2
- BCOR | c.2752C>T p.Q918* | Nonsense Mutation (SNP) | VAF 67/83 reads (81%) | catalogued as COSV60706659; called by muse, mutect2, varscan2
- CPSF6 | c.339A>C p.K113N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57014418; called by muse, mutect2
- CSN3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs765381118, COSV100515249, COSV59244055; called by muse, mutect2, varscan2
- DELE1 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV52004800; called by muse, mutect2, varscan2
- DENND6A | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs926530127, COSV60768586; called by muse, mutect2, varscan2
- DGKD | c.1894G>A p.D632N (on ENST00000264057 / NM_152879.3; = p.D588N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs779772196, COSV51045219; called by muse, mutect2, varscan2
- DGKK | c.3504G>A p.L1168= | Splice Region (SNP) | VAF 18/22 reads (82%) | catalogued as COSV65707316; called by muse, mutect2, varscan2
- DIS3L2 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV56053910; called by muse, mutect2, varscan2
- DMAP1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 74/183 reads (40%) | catalogued as rs776362349, COSV60000603; called by muse, mutect2, varscan2
- DVL2 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1264036091, COSV50035784; called by muse, mutect2, varscan2
- EIF4B | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs763817075, COSV50402869; called by muse, mutect2, varscan2
- FBXO24 | c.265C>T p.R89C (on ENST00000241071 / NM_033506.3; = p.R127C on NM_012172.5) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs563719782, COSV53823656; called by muse, mutect2, varscan2
- FILIP1 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 333/647 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756805292, COSV52729054; called by muse, mutect2, varscan2
- GDF2 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1001252237; called by muse, mutect2, varscan2
- GLUD2 | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60151893; called by muse, mutect2, varscan2
- HAL | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV54117675; called by muse, mutect2, varscan2
- HDAC2 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV64038107; called by muse, mutect2, varscan2
- HTR3E | c.446G>A p.R149H (on ENST00000415389 / NM_001256613.1; = p.R164H on NM_182589.2) | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as rs954199990, COSV58946473; called by muse, mutect2, varscan2
- INSL6 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV67562521; called by muse, mutect2, varscan2
- ITGAX | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs771872674, COSV51645483; called by muse, mutect2, varscan2
- KCTD2 | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 40/84 reads (48%) | catalogued as COSV59368273; called by muse, mutect2
- KRT79 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV57939712, COSV57939941; called by muse, mutect2, varscan2
- LHX9 | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 166/448 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV61328580; called by muse, mutect2, varscan2
- LRTM2 | c.731T>G p.M244R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1168695808, COSV54564926; called by muse, mutect2, varscan2
- ME3 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.044); catalogued as COSV100661102; called by mutect2, varscan2
- MROH9 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs201493255, COSV63011223; called by muse, mutect2, varscan2
- MYO9B | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV68278952; called by muse, mutect2, varscan2
- NES | c.3206A>T p.D1069V | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV63960983; called by muse, mutect2, varscan2
- NEU2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs753794682, COSV52092505; called by muse, varscan2
- NFYB | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV53529687; called by muse, mutect2, varscan2
- NPTX2 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377548219; called by muse, mutect2, varscan2
- OR4K5 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 305/731 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs559771911, COSV60003436; called by muse, mutect2, varscan2
- PKHD1L1 | c.7704C>A p.N2568K | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV65742629; called by muse, mutect2, varscan2
- PLCG1 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54815150; called by muse, mutect2, varscan2
- PTEN | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as CM110131, COSV64288635, COSV64288792; called by muse, mutect2, varscan2
- SCAP | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55561132; called by muse, mutect2, varscan2
- SEMG1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.981); catalogued as rs199781597; called by muse, mutect2, varscan2
- SH3TC1 | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs776646348, COSV55283980; called by muse, mutect2, varscan2
- SHANK1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767501457, COSV53243521; called by muse, mutect2, varscan2
- SLC16A13 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as COSV57274206; called by muse, mutect2, varscan2
- SLFN5 | c.1261T>C p.F421L | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV55481029; called by muse, mutect2, varscan2
- SOX30 | c.764A>C p.Q255P | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV53937327; called by muse, mutect2, varscan2
- TIAM2 | c.3901G>A p.G1301R | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866159919, COSV51640189; called by muse, mutect2, varscan2
- TRIM29 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); catalogued as rs1330707550, COSV59280188; called by muse, mutect2
- TRPC7 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1238726354, COSV61457626; called by muse, mutect2, varscan2
- TTN | c.19940C>T p.T6647M (on ENST00000591111; = p.T5720M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | PolyPhen benign (0.023); catalogued as rs765257439, COSV60026146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.7724G>T p.S2575I (on ENST00000591111; = p.S2529I on NM_003319.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | PolyPhen benign (0.106); catalogued as COSV60042405; called by muse, mutect2, varscan2
- ZNF492 | c.1256A>C p.K419T | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71761937; called by muse, mutect2, varscan2
- AMZ1 | c.89dup p.L31Afs*121 | Frame Shift Ins (INS) | VAF 120/426 reads (28%) | called by mutect2, pindel, varscan2
- DNAH8 | c.635del p.L212Rfs*2 | Frame Shift Del (DEL) | VAF 14/103 reads (14%) | called by mutect2, pindel, varscan2
- GPR75 | c.1566_1574dup p.V524_Q525insHLV | In Frame Ins (INS) | VAF 26/152 reads (17%) | called by mutect2, varscan2
- ATP13A4 | c.2494C>T p.L832= | Silent (SNP) | VAF 58/117 reads (50%) | catalogued as COSV61319859; called by muse, mutect2, varscan2
- CCDC141 | c.4152G>A p.R1384= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV55373122; called by muse, mutect2, varscan2
- CD163L1 | c.3354C>T p.R1118= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs750899069, COSV58015706; called by muse, mutect2
- FAM117A | c.1233G>A p.P411= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs371670103; called by muse, mutect2, varscan2
- FBP1 | c.387C>T p.C129= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV64689295; called by muse, mutect2, varscan2
- FLG | c.1320C>T p.H440= | Silent (SNP) | VAF 249/506 reads (49%) | catalogued as rs376019219; called by muse, mutect2, varscan2
- GJB5 | c.624G>A p.L208= | Silent (SNP) | VAF 71/192 reads (37%) | catalogued as COSV58356129; called by muse, mutect2, varscan2
- NFIX | c.639G>A p.Q213= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV62177157; called by muse, mutect2, varscan2
- PCNX2 | c.1500A>G p.T500= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as COSV50799309; called by muse, mutect2, varscan2
- SCARB1 | c.891C>T p.P297= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV55547417; called by muse, mutect2, varscan2
- SYNE1 | c.15837C>T p.L5279= (on ENST00000367255 / NM_182961.4; = p.L5208= on NM_033071.3) | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as COSV54975573; called by muse, mutect2, varscan2
- TRIM71 | c.120G>A p.T40= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV67470832; called by muse, mutect2, varscan2
- MORF4 | n.763C>A | RNA (SNP) | VAF 155/346 reads (45%) | called by muse, mutect2, varscan2
- SSPOP | n.9794G>C | RNA (SNP) | VAF 19/101 reads (19%) | catalogued as COSV65127474, COSV65129774; called by muse, mutect2, varscan2
